Gene-level copy-number profile of tumor specimen TCGA-CL-5917-01A from TCGA case TCGA-CL-5917, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 71.4 years (26,084 days).
Specimen TCGA-CL-5917-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.2deed5dd-bfd5-463a-8961-9f46b00eaea5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CL-5917-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/470a77e3-0681-4a26-a09e-2decdd08641e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 2,184; copy number 2: 38,414; copy number 3: 9,850; copy number 4: 3,454; copy number 5: 4,530; copy number 6: 1,101; copy number 7: 284.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CL-5917-01A-11D-1656-01): tumor purity 0.79, ploidy 2.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:15,021,553–15,280,873, 3 genes: RNU6-1159P, RNU6-115P, RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,495 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:35,235,475–35,796,550, 1 gene, copy number 5 (within-gene range 1–5): UNC5D.
- chr8:35,525,176–36,321,404, 11 genes, copy number 5: LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2.
- chr8:36,987,977–145,066,685, 1,707 genes, copy number 5 (broad region; genes not listed).
- chr12:19,089,151–34,166,954, 280 genes, copy number 6 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 5 (broad region; genes not listed).
- chr15:22,983,192–23,630,075, 22 genes, copy number 6 (within-gene range 2–6): TUBGCP5, ELMO2P1, GOLGA6L1, AC116165.1, GOLGA8DP, RN7SL106P, ABCB10P1, AC116165.2, MIR4509-1, AC116165.3, AC242376.1, HERC2P7, AC100756.2, AC100756.1, GOLGA8S, RN7SL536P, AC100756.3, HERC2P6, GOLGA6L2, MIR4508, MKRN3, AC126407.1.
- chr20:19,693,209–64,313,132, 1,083 genes, copy number 6–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,184. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
